MMRF case MMRF_2144 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/abec123c-77e7-48b8-9054-41cd52fb1db8

Demographics
Sex at birth: male; Race: white; Ethnicity: not hispanic or latino; Age at index: 71 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 72.0 years (26,301 days); ISS stage: I; Days to last known disease status: 921 days (2.5 years); Days to last follow up: 921 days (2.5 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 68 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 253 days.

Follow-up (1 entry)
- Follow-up contact recording only the day: day 921.

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -38 (ECOG 1): M Protein 4.95 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.694 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 79.9 mg/dL; Immunoglobulin G 70.4 g/L; Immunoglobulin A 0.49 g/L; Immunoglobulin M 0.26 g/L; Beta 2 Microglobulin 3.45 µg/mL; Lactate Dehydrogenase 2.62 µkat/L; Hemoglobin 7.13 mmol/L; Leukocytes 7.9 ×10⁹/L; Absolute Neutrophil 4.1 ×10⁹/L; Platelets 193 ×10⁹/L; Creatinine 94.6 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 11.6 g/dL; Glucose 6.66 mmol/L; C-Reactive Protein 0.38 mg/dL.
- Day 57 (ECOG 1): M Protein 0.44 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 0.789 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.804 mg/dL; Immunoglobulin G 9.14 g/L; Immunoglobulin A 0.42 g/L; Immunoglobulin M 0.31 g/L; Lactate Dehydrogenase 3.07 µkat/L; Hemoglobin 6.57 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 5.2 ×10⁹/L; Platelets 63 ×10⁹/L; Creatinine 85.7 µmol/L; Blood Urea Nitrogen 8.21 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 5.6 g/dL; Glucose 6.22 mmol/L.
- Day 163 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.51 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.98 mg/dL; Immunoglobulin G 5.49 g/L; Immunoglobulin A 0.64 g/L; Immunoglobulin M 0.16 g/L; Lactate Dehydrogenase 2.9 µkat/L; Hemoglobin 7.87 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 8.5 ×10⁹/L; Platelets 226 ×10⁹/L; Creatinine 80.4 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 37 g/L; Total Protein 6.3 g/dL; Glucose 6.66 mmol/L.
- Day 221 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.1 mg/dL; Immunoglobulin G 7.13 g/L; Immunoglobulin A 0.85 g/L; Immunoglobulin M 0.22 g/L; Beta 2 Microglobulin 2.4 µg/mL; Lactate Dehydrogenase 2.92 µkat/L; Hemoglobin 8.68 mmol/L; Leukocytes 10.4 ×10⁹/L; Absolute Neutrophil 7.9 ×10⁹/L; Platelets 208 ×10⁹/L; Creatinine 65.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 42 g/L; Total Protein 6.6 g/dL; Glucose 3.96 mmol/L.
- Day 281 (ECOG 1): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.32 mg/dL; Immunoglobulin G 9.34 g/L; Immunoglobulin A 2.18 g/L; Immunoglobulin M 0.32 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.3 ×10⁹/L; Absolute Neutrophil 4.6 ×10⁹/L; Platelets 259 ×10⁹/L; Creatinine 73.4 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.25 mmol/L; Albumin 36 g/L; Total Protein 6.4 g/dL; Glucose 5.5 mmol/L.
- Day 372 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.198 mg/dL; Immunoglobulin G 9.99 g/L; Immunoglobulin A 3.65 g/L; Immunoglobulin M 0.27 g/L; Lactate Dehydrogenase 2.38 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.6 ×10⁹/L; Absolute Neutrophil 3.9 ×10⁹/L; Platelets 220 ×10⁹/L; Creatinine 87.5 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.23 mmol/L; Albumin 40 g/L; Total Protein 7 g/dL; Glucose 7.26 mmol/L.
- Day 459 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 7.05 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.88 mg/dL; Immunoglobulin G 10 g/L; Immunoglobulin A 3.95 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.53 µkat/L; Hemoglobin 8 mmol/L; Leukocytes 6.8 ×10⁹/L; Absolute Neutrophil 3.1 ×10⁹/L; Platelets 91 ×10⁹/L; Creatinine 95.5 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.28 mmol/L; Albumin 38 g/L; Total Protein 6.7 g/dL; Glucose 5.39 mmol/L.
- Day 575 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 3.02 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.42 mg/dL; Immunoglobulin G 7.78 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.17 g/L; Lactate Dehydrogenase 2.87 µkat/L; Hemoglobin 7.25 mmol/L; Leukocytes 7.8 ×10⁹/L; Absolute Neutrophil 5.38 ×10⁹/L; Platelets 209 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.23 mmol/L; Albumin 31 g/L; Total Protein 5.9 g/dL; Glucose 7.32 mmol/L.
- Day 715 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 5.39 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.21 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 5.44 g/L; Immunoglobulin M 0.24 g/L; Lactate Dehydrogenase 2.28 µkat/L; Hemoglobin 8.31 mmol/L; Leukocytes 6.4 ×10⁹/L; Absolute Neutrophil 3.3 ×10⁹/L; Platelets 200 ×10⁹/L; Creatinine 70.7 µmol/L; Blood Urea Nitrogen 3.93 mmol/L; Calcium 2.13 mmol/L; Albumin 37 g/L; Total Protein 6 g/dL; Glucose 6.11 mmol/L.
- Day 809 (ECOG 0): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.86 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.88 mg/dL; Immunoglobulin G 9.48 g/L; Immunoglobulin A 5.14 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 2.35 µkat/L; Hemoglobin 8.25 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 3.8 ×10⁹/L; Platelets 157 ×10⁹/L; Creatinine 75.1 µmol/L; Blood Urea Nitrogen 4.28 mmol/L; Calcium 2.08 mmol/L; Albumin 34 g/L; Total Protein 6.2 g/dL; Glucose 4.18 mmol/L.
- Day 835: M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 4.73 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.97 mg/dL; Immunoglobulin G 9.24 g/L; Immunoglobulin A 5.34 g/L; Immunoglobulin M 0.22 g/L; Lactate Dehydrogenase 4.18 µkat/L; Hemoglobin 8.99 mmol/L; Leukocytes 6.9 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 154 ×10⁹/L; Creatinine 90.2 µmol/L; Blood Urea Nitrogen 5.71 mmol/L; Calcium 2.23 mmol/L; Albumin 35 g/L; Total Protein 6.7 g/dL; Glucose 4.35 mmol/L.

Other clinical attributes
- Day -38: Weight: 74 kg; Height: 167 cm.

Biospecimens (2 samples)
- Sample MMRF_2144_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -38 days.
- Sample MMRF_2144_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -38 days.
